Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5201, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5201-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-5201

Clinical Diagnosis & History:

Patient with metastatic RCC to lungs.

Specimens Submitted:

- 1: Kidney, left, total nephrectomy
- 2: Lymph nodes, suprahilal, left, and adrenal gland, excision
- 3: Lymph nodes, pre-aortic, excision
- 4: SP: Para-aortic lymph nodes

DIAGNOSIS:

1. Kidney, left, total nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade IV/IV ✓

Tumor Size:

Greatest diameter is 9.5 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Tumor is identified in muscular vessels in the region of the renal sinus/hilum ✓

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Involved by tumor (see Part 2)

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

Lymph nodes, suprahilal, left, and adrenal gland, excision

Clear cell carcinoma involving adrenal gland.

No lymph nodes identified.

[page 2 of 4]
3. Lymph nodes, pre-aortic, excision [REDACTED]
Lymph Nodes:
Not involved
Number of nodes examined: 3

4. SP: Para-aortic lymph nodes [REDACTED]:
Lymph Nodes:
Not involved
Number of nodes examined: 1

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out *** [REDACTED]

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1.) The specimen is received fresh for consultation labeled "Left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 454 g in total. The kidney measures 11 x 9 x 5.5 cm. The attached ureter measures 2.5 cm in length and 0.6 cm in diameter. The attached renal vein measures 1.1 cm in length and 1.6 cm in diameter. There are two renal arteries which are up to 95 to 100% stenotic. The remaining renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a 9.5 x 6.1 x 5.5 cm, circumscribed, spongy to firm, white to golden yellow, focally fibrotic and hemorrhagic mass which protrudes into the renal vein 1.7 cm away from the renal vein margin and abuts the renal capsule but does not appear to go through or into the perirenal fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction containing a 0.8 x 0.7 x 0.3 cm cyst. The cortex measures 1.0 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for frozen consultation, TPS and for permanent sections.

Summary of sections:

FSC -- frozen section control
UVM -- ureteral and vessel margins
T-- tumor
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney

2). The specimen is received fresh labeled "left supra hilar lymph nodes and adrenal gland" and consists of a 5.5 x 1.8 x 1.2 cm intact adrenal gland weighing 5.5 g, with attached fibrofatty adipose tissue measuring 8.0 x 3.4 x 1.0 cm. Within the fat is a 2.8 x 2.5 x 2.5 cm firm purple tan lymph node, with three additional small possible lymph nodes ranging from 0.3 cm up to 0.4 cm in

[page 3 of 4]
greatest dimension. The largest lymph node is sectioned to reveal a variegated yellow-gray hemorrhagic cut surface with a central gelatinous component. The adrenal gland is sectioned to reveal a grossly unremarkable orange cortical surface with a tan-white homogeneous medullary cut surface. Representative sections are submitted.

Summary of sections:

A-adrenal gland

LLN-largest lymph node

LN-additional possible lymph nodes

3).The specimen is received in formalin, labeled "pre-aortic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.8 to 3.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

SLN-- serially sectioned lymph node

4).The specimen is received in formalin, labeled "para-aortic lymph nodes" and consists of a pink tan firm lymph node measuring 1.3 cm in greatest dimension. The lymph node is entirely submitted.

Summary of sections:

LN -- lymph node

Summary of Sections:

Part 1: Kidney, left, total nephrectomy

Block	Sect. Site	PCs
1	FSC	1
2	K	2
2	RP	2
3	T	3
3	THF	3
2	TK	2
2	TSF	2
1	UVM	1

Part 2: Lymph nodes, supra hilar, left, and adrenal gland, excision

Block	Sect. Site	PCs
1	a	1
2	lin	2
1	ln	1

Part 3: Lymph nodes, pre-aortic, excision

Block	Sect. Site	PCs
1	ln	1
3	sln	3

Part 4: SP: Para-aortic lymph nodes

Block	Sect. Site	PCs
1	ln	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 4 of 4]
[REDACTED] [REDACTED]
[REDACTED] [REDACTED] [REDACTED]
1. FROZEN SECTION DIAGNOSIS: SP; LEFT KIDNEY [REDACTED]: RENAL CORTICAL NEOPLASM
(NON-UROTHELIAL). [REDACTED]
PERMANENT DIAGNOSIS: SAME

[REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file 36d3e403-d531-431f-9426-9d5a8f2f42e8 (TCGA-BP-5201.C849E5F0-2600-499B-84E7-4DB9E19629FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).